HCMI case HCM-WCMC-1285-C54 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0dc9723e-f5ff-4fe3-98a4-325a23e61b5f

Demographics
Sex at birth: female; Year of birth: 1987; Vital status: Alive.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 34.0 years (12,423 days); AJCC staging edition: 8th; AJCC pathologic T: T2; AJCC pathologic N: N2a; FIGO stage: Stage IIIC2; Tumor grade: G2; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: No; Sites of involvement: Cervix / Pelvic Lymph Node(s) / Lymph node, NOS / Uterus.
   Pathology details: Lymph node involvement: Positive; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 35 days.
   Treatment given: Treatment type: Brachytherapy, NOS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 66 days; Days to treatment end: 111 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 66 days; Days to treatment end: 94 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bortezomib + Carboplatin + Paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 166 days; Days to treatment end: 229 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (4 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence type: Regional; Progression or recurrence anatomic site: Pelvic lymph nodes; Days to progression: 0 days.
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence type: Regional; Progression or recurrence anatomic site: Intra-abdominal lymph nodes; Days to progression: 0 days.
- Days to follow up: 628 days (1.7 years); Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 454.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 51.3 kg; Height: 156.2 cm; BMI: 21.
- Timepoint category: Prior to Diagnosis; Comorbidities: Lynch Syndrome; Hormone replacement therapy type: Estrogen only; Risk factors: Lynch Syndrome.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-WCMC-1285-C54-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide HCM-WCMC-1285-C54-01A-01-S1-HE: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 40; Percent normal cells: 60; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-WCMC-1285-C54-01A-01-S2: Section location: Bottom; Percent tumor cells: 20; Percent tumor nuclei: 20; Percent normal cells: 80; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-WCMC-1285-C54-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-WCMC-1285-C54-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
